Somatic mutation profile of tumor specimen TARGET-10-PATWHB-09A (aliquot TARGET-10-PATWHB-09A-01D) from TARGET case TARGET-10-PATWHB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,904 days).
Specimen TARGET-10-PATWHB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8845f4e-3263-4de3-8656-91d24ae9dc0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWHB-10A (Blood Derived Normal), aliquot TARGET-10-PATWHB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/860224fc-b9db-4398-8db5-74b525e0ed05

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Ins 3, Intron 2, RNA 2, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP5 | c.96T>G p.D32E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70519244; called by muse, mutect2, varscan2
- DICER1 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1555370815, COSV58630473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETS2 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs201321686, COSV62874890; called by muse, mutect2, varscan2
- GIN1 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.096); catalogued as rs759917916, COSV67537797; called by muse, mutect2, varscan2
- HTR4 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs376809075; called by muse, mutect2, varscan2
- KITLG | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57204738; called by muse, mutect2, varscan2
- MXRA5 | c.6635C>T p.T2212M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373612920, COSV54239479; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>G p.I1680S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- NYAP1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs768207302, COSV55718562; called by muse, mutect2, varscan2
- OR4C6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs146965889, COSV100051763; called by muse, mutect2
- PAPPA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs576620013, COSV62772155; called by muse, mutect2, varscan2
- PHETA1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144801881; called by muse, mutect2, varscan2
- PPP2R3A | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs199925843; called by muse, mutect2, varscan2
- RYR3 | c.12823G>A p.D4275N (on ENST00000389232; = p.D4276N on NM_001036.6) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.55); catalogued as COSV66777323, COSV66782356; called by muse, mutect2, varscan2
- SUZ12 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV59501224, COSV59504168; called by muse, mutect2, varscan2
- UNC80 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs777091779, COSV55910256; called by muse, mutect2, varscan2
- IL7R | c.723_727delinsACACTGCA p.L242_L243delinsHCI | In Frame Ins (INS) | VAF 32/57 reads (56%) | called by pindel, varscan2*
- LTBP3 | c.398dup p.D134Gfs*60 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- MGA | c.3744dup p.E1249Rfs*25 | Frame Shift Ins (INS) | VAF 30/67 reads (45%) | called by mutect2, varscan2
- SPATA32 | c.1040_1041insGTCCTTTC p.P348Sfs*26 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1080C>T p.H360= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs199716501; called by muse, mutect2, varscan2
- CASP14 | c.267C>T p.H89= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1408672307, COSV55665040, COSV99693121; called by muse, mutect2, varscan2
- ILDR2 | c.489G>A p.L163= | Silent (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- MUC5AC | c.15141C>T p.S5047= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs753199518; called by muse, mutect2, varscan2
- PRPF8 | c.2199G>A p.T733= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs777885967; called by muse, mutect2, varscan2
- PRRT4 | c.348C>T p.T116= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1423565237; called by muse, mutect2, varscan2
- CFAP100 | c.225+19C>T | Intron (SNP) | VAF 20/59 reads (34%) | catalogued as rs371091744; called by muse, mutect2, varscan2
- CYP2A7P1 | n.400G>A | RNA (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- GLYATL1 | n.191C>T | RNA (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- MASP2 | c.544+383G>A | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs897458953; called by muse, mutect2, varscan2
